Somatic mutation profile of tumor specimen TCGA-DJ-A1QO-01A (aliquot TCGA-DJ-A1QO-01A-11D-A14W-08) from TCGA case TCGA-DJ-A1QO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 69.1 years (25,232 days).
Specimen TCGA-DJ-A1QO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9161b97-d3d1-4136-92b2-7dabd2be5291.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QO-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QO-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57acad6a-46d6-4441-bbeb-7a7363e166e8

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRV1 | c.13832A>G p.K4611R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV67996909; called by muse, mutect2, varscan2
- ARID1B | c.4159C>T p.Q1387* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as rs1554235552, COSV51684267, COSV99270566; called by muse, mutect2, varscan2
- CNGA4 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as rs532111437, COSV66005224; called by muse, mutect2, varscan2
- DNAI2 | c.152T>A p.I51N | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs564894784, COSV56763274; called by muse, mutect2, varscan2
- NAV3 | c.6103C>T p.P2035S (on ENST00000397909 / NM_001024383.2; = p.P2013S on NM_014903.6) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57117615; called by muse, mutect2, varscan2
- PCDHA8 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1554139153, COSV65340951; called by muse, mutect2, varscan2
- RBM4B | c.984A>T p.L328F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV59498398; called by muse, mutect2, varscan2
- SAMD15 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV53628277; called by muse, mutect2, varscan2
- TAAR5 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57800045; called by muse, mutect2, varscan2
- TTN | c.24810G>C p.E8270D (on ENST00000591111; = p.E7343D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | PolyPhen benign (0); catalogued as COSV60405846; called by muse, mutect2, varscan2
- ZBTB40 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as COSV65146632; called by muse, mutect2
- ZNF397 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1235087926; called by muse, mutect2
- SHLD2 | c.479_480del p.G160Efs*4 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | called by mutect2, pindel, varscan2
- HTATIP2 | c.702G>A p.G234= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV58181491; called by muse, mutect2, varscan2
- KCMF1 | c.756C>T p.R252= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV69055072; called by muse, mutect2, varscan2
- MYCBP2 | c.8085G>A p.E2695= (on ENST00000357337; = p.E2733= on NM_015057.5) | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as COSV62042601; called by muse, mutect2, varscan2
- ZNF141 | c.573A>G p.V191= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs1003198273, COSV53662496; called by muse, mutect2, varscan2
